Somatic mutation profile of tumor specimen MMRF_1783_2_BM_CD138pos (aliquot MMRF_1783_2_BM_CD138pos_T1_KHS5U_L11614) from MMRF case MMRF_1783, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.9 years (21,139 days).
Specimen MMRF_1783_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ecc94f7-0125-4081-8b69-768dff4992cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1783_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1783_1_PB_Whole_C3_KBS5U_L05398; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cdac9ba-0ed3-4f5b-a4a0-f01457de57bb

The open-access MAF lists 117 somatic variants for this specimen: 48 protein-altering or splice-affecting, 19 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 28, Silent 19, Intron 13, 5'Flank 4, 5'UTR 3, Frame Shift Del 1, 3'Flank 1, Splice Region 1, RNA 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3075C>A p.N1025K | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1360363021; called by muse, mutect2, varscan2
- AKAP10 | c.1095C>G p.F365L | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.366); catalogued as COSV99855650; called by muse, mutect2
- AKAP13 | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767973733; called by muse, mutect2, varscan2
- BCL9 | c.3058A>G p.S1020G | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs918637766; called by muse, mutect2
- CEP350 | c.940A>G p.M314V | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs755183539; called by muse, mutect2, varscan2
- CHRD | c.383-8G>T | Splice Region (SNP) | VAF 26/343 reads (8%) | catalogued as rs769509825; called by muse, mutect2
- H2AC6 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs987728493, COSV58414954; called by muse, mutect2, varscan2
- H3C8 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs992932759, COSV59953008; called by muse, mutect2, varscan2
- HAPLN1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs555462462, COSV57145600; called by muse, mutect2, varscan2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, varscan2
- IGHV2-70 | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as rs376400758; called by muse, varscan2
- IGKV4-1 | c.145G>T p.V49F | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs138603647; called by muse, mutect2, varscan2
- IGLC2 | c.251G>C p.S84T | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs528109051; called by muse, varscan2
- IGLV1-44 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.1); catalogued as rs180819320; called by muse, mutect2, varscan2
- IGLV5-45 | c.46+2T>C p.X16_splice | Splice Site (SNP) | VAF 38/148 reads (26%) | catalogued as rs763479033; called by muse, mutect2, varscan2
- LIMK1 | c.1624A>T p.I542F | Missense Mutation (SNP) | VAF 98/391 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60281670; called by muse, mutect2, varscan2
- LRRN3 | c.565A>T p.N189Y | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs762844497; called by muse, mutect2, varscan2
- MYO1D | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs545273791, COSV59022055; called by muse, mutect2, varscan2
- NATD1 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.237); catalogued as rs373476359; called by muse, mutect2, varscan2
- NEU4 | c.742C>T p.R248C (on ENST00000391969 / NM_001167602.3; = p.R260C on NM_080741.4) | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755490713; called by muse, mutect2, varscan2
- PBX4 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV52060541; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.177); catalogued as COSV52788468; called by muse, mutect2, varscan2
- RTP5 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs768854977, COSV58319270; called by muse, mutect2, varscan2
- THADA | c.2409A>C p.K803N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375611743; called by muse, mutect2, varscan2
- C6orf58 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- CENPF | c.5197C>T p.P1733S | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL12A1 | c.425T>G p.V142G | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- COL3A1 | c.860del p.N287Mfs*123 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- DCHS1 | c.4357G>A p.A1453T | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GAD2 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- HEATR5B | c.4631T>G p.F1544C | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1-69D | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 68/370 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, varscan2
- INTS12 | c.373A>T p.T125S | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- INTS5 | c.1216T>A p.L406M | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- MARCHF6 | c.2048A>C p.Y683S | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MGAM2 | c.5353A>G p.N1785D | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2
- MOCS2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PIP5K1C | c.1553A>T p.E518V | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); called by muse, mutect2
- PRR32 | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PZP | c.3745A>G p.N1249D | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBNO2 | c.2594T>C p.F865S | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIX1 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SOX15 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- TRMT112 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- USH2A | c.13443G>T p.R4481S | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USH2A | c.1111A>C p.I371L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ZFYVE28 | c.1289G>C p.W430S | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF513 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ADAMTS2 | c.1092C>A p.I364= | Silent (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- DPP8 | c.76C>T p.L26= (on ENST00000341861 / NM_001320875.2; = p.L10= on NM_017743.6) | Silent (SNP) | VAF 63/302 reads (21%) | catalogued as rs1230403833; called by muse, mutect2, varscan2
- FAM193A | c.375G>T p.A125= | Silent (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.357A>C p.I119= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs139383686; called by muse, varscan2
- IGHV2-70 | c.273C>T p.S91= | Silent (SNP) | VAF 42/175 reads (24%) | catalogued as rs115694694; called by muse, varscan2
- IGLV5-45 | c.267A>G p.G89= | Silent (SNP) | VAF 24/177 reads (14%) | catalogued as rs375705788; called by muse, varscan2
- IKZF3 | c.1170C>T p.D390= | Silent (SNP) | VAF 72/332 reads (22%) | called by muse, mutect2, varscan2
- LTB | c.252C>T p.S84= | Silent (SNP) | VAF 52/234 reads (22%) | catalogued as rs4647186, COSV65815060; called by muse, mutect2, varscan2
- MYBPH | c.360G>A p.V120= | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- NT5DC2 | c.622C>T p.L208= | Silent (SNP) | VAF 84/415 reads (20%) | called by muse, mutect2, varscan2
- PCNX2 | c.558A>T p.S186= | Silent (SNP) | VAF 62/305 reads (20%) | called by muse, mutect2, varscan2
- POLE3 | c.348G>A p.S116= | Silent (SNP) | VAF 50/204 reads (25%) | catalogued as rs746011753; called by muse, mutect2, varscan2
- PTPRN2 | c.852C>A p.A284= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV101233861; called by muse, mutect2
- RAB44 | c.2904G>A p.L968= | Silent (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- RGS7 | c.183C>T p.D61= | Silent (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- RGSL1 | c.507C>A p.T169= | Silent (SNP) | VAF 29/203 reads (14%) | called by muse, mutect2, varscan2
- SPTBN4 | c.3570G>A p.A1190= | Silent (SNP) | VAF 42/193 reads (22%) | catalogued as rs1213384597; called by muse, mutect2, varscan2
- TRHDE | c.531C>G p.T177= | Silent (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- ZNF688 | c.708C>T p.C236= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- ANK2 | c.85-57362G>A | Intron (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- ANKIB1 | c.*1491T>A | 3'UTR (SNP) | VAF 32/142 reads (23%) | called by muse, mutect2, varscan2
- APOLD1 | c.*812T>G | 3'UTR (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021243 G>A | 5'Flank (SNP) | VAF 42/208 reads (20%) | called by muse, varscan2
- BCL7A | chr12:122021244 A>T | 5'Flank (SNP) | VAF 46/210 reads (22%) | called by muse, varscan2
- BCL7A | chr12:122021434 G>C | 5'Flank (SNP) | VAF 62/252 reads (25%) | called by muse, mutect2, varscan2
- BTBD3 | c.327-14G>T | Intron (SNP) | VAF 98/518 reads (19%) | called by muse, mutect2, varscan2
- C16orf97 | n.132C>T | RNA (SNP) | VAF 6/102 reads (6%) | catalogued as rs975560512; called by muse, mutect2
- CNGB1 | c.*184G>A | 3'UTR (SNP) | VAF 60/305 reads (20%) | catalogued as COSV51904198; called by muse, mutect2, varscan2
- DCDC2 | c.*12A>G | 3'UTR (SNP) | VAF 55/252 reads (22%) | catalogued as rs758240952; called by muse, mutect2, varscan2
- EGR1 | c.-60C>T | 5'UTR (SNP) | VAF 5/44 reads (11%) | catalogued as rs1432434904; called by muse, mutect2, varscan2
- FANCD2 | c.65-470C>T | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2
- FCHSD1 | c.*240C>G | 3'UTR (SNP) | VAF 29/202 reads (14%) | catalogued as COSV51838574; called by muse, mutect2, varscan2
- FILIP1 | c.*171T>A | 3'UTR (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- GABRB3 | c.*1940C>A | 3'UTR (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- GABRG3 | c.712+40G>A | Intron (SNP) | VAF 36/325 reads (11%) | catalogued as COSV61538491; called by muse, mutect2, varscan2
- GBX2 | c.-42C>T | 5'UTR (SNP) | VAF 6/44 reads (14%) | catalogued as rs991398264; called by muse, mutect2
- GPR12 | c.-104G>A | 5'UTR (SNP) | VAF 27/168 reads (16%) | called by muse, mutect2, varscan2
- GPRC5A | c.*3607C>T | 3'UTR (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- HOXD9 | chr2:176122346 G>A | 5'Flank (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- LTB | c.163-57G>A | Intron (SNP) | VAF 110/556 reads (20%) | catalogued as rs553997400; called by muse, varscan2
- LTB | c.163-141G>A | Intron (SNP) | VAF 56/270 reads (21%) | catalogued as rs4647180; called by muse, varscan2
- MELTF | c.712+2047A>G | Intron (SNP) | VAF 27/170 reads (16%) | called by muse, mutect2, varscan2
- MSRB3 | c.*490G>A | 3'UTR (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- PAX3 | chr2:222200892 A>G | 3'Flank (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*4729C>T | 3'UTR (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- POLRMT | c.823-50G>A | Intron (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- REG3G | c.*210A>C | 3'UTR (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2
- RGS21 | c.*814C>A | 3'UTR (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- RGS5 | c.*1990C>G | 3'UTR (SNP) | VAF 48/130 reads (37%) | called by muse, mutect2, varscan2
- SHQ1 | c.*788C>T | 3'UTR (SNP) | VAF 25/142 reads (18%) | called by muse, mutect2, varscan2
- SLC52A3 | c.1197+90G>A | Intron (SNP) | VAF 9/66 reads (14%) | catalogued as rs777023600; called by muse, mutect2, varscan2
- SOS1 | c.*2198A>T | 3'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- SPATA18 | c.*1239G>A | 3'UTR (SNP) | VAF 31/165 reads (19%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*95A>G | 3'UTR (SNP) | VAF 53/222 reads (24%) | called by muse, mutect2, varscan2
- STAT1 | c.*451T>A | 3'UTR (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- STEAP4 | c.*4854T>G | 3'UTR (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- STX18 | c.703-124C>G | Intron (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- SYBU | c.*795C>T | 3'UTR (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- SYBU | c.*428T>G | 3'UTR (SNP) | VAF 47/207 reads (23%) | called by muse, mutect2, varscan2
- SYS1 | c.*1281C>G | 3'UTR (SNP) | VAF 29/131 reads (22%) | called by muse, mutect2, varscan2
- SYT11 | c.*814T>G | 3'UTR (SNP) | VAF 10/117 reads (9%) | called by muse, mutect2
- TAP2 | c.*2657T>C | 3'UTR (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- TBC1D1 | c.*1502A>C | 3'UTR (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- TBC1D1 | c.*1503C>A | 3'UTR (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- TNK2 | c.-18-6872C>T | Intron (SNP) | VAF 50/192 reads (26%) | catalogued as rs962746173; called by muse, mutect2, varscan2
- WFDC1 | c.605-133G>T | Intron (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- YAF2 | c.27-35C>A | Intron (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- ZCCHC4 | c.*1030G>A | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- ZNF785 | c.*76G>T | 3'UTR (SNP) | VAF 88/525 reads (17%) | called by muse, mutect2, varscan2
